Somatic mutation profile of cancer-model specimen HCM-WCMC-0505-C16-85A (3D Organoid, passage 12; aliquot HCM-WCMC-0505-C16-85A-01D-A79N-36), derived from the primary tumor of HCMI case HCM-WCMC-0505-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.9 years (27,705 days).
Specimen HCM-WCMC-0505-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d62775ca-2dc2-4479-b0ba-7d79d6808647.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0505-C16-10A (Blood Derived Normal), aliquot HCM-WCMC-0505-C16-10A-01D-A79N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c28b8cc4-4250-464b-92ad-6950e4749b4a

The open-access MAF lists 322 somatic variants for this specimen: 236 protein-altering or splice-affecting, 78 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 208, Silent 78, Nonsense Mutation 13, Intron 6, Frame Shift Del 6, Frame Shift Ins 4, In Frame Del 3, 3'UTR 1, Translation Start Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 297/298 reads (100%) | catalogued as rs387906432, CM900085, COSV64270158; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 87/290 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTR6 | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 144/410 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1247364637; called by muse, mutect2, varscan2
- ADIPOR2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 130/759 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777599853, COSV63947216; called by muse, mutect2, varscan2
- AICDA | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 366/664 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs761363877, COSV57563767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AOC3 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 210/647 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.848); catalogued as COSV53828662; called by muse, mutect2, varscan2
- ARHGEF11 | c.3625C>T p.R1209* | Nonsense Mutation (SNP) | VAF 580/898 reads (65%) | catalogued as rs1036932379, COSV59352521; called by muse, mutect2
- ASTN2 | c.1288A>G p.S430G (on ENST00000313400 / NM_001365069.1; = p.S379G on NM_014010.5) | Missense Mutation (SNP) | VAF 184/322 reads (57%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV100528129; called by muse, mutect2, varscan2
- B4GALNT3 | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 177/775 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1265235287; called by muse, mutect2, varscan2
- BMPER | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 23/779 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51826864; called by muse, mutect2
- C16orf95 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 149/474 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs747256197; called by muse, mutect2, varscan2
- C19orf44 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 307/307 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.162); catalogued as rs752225842; called by muse, mutect2, varscan2
- C2orf78 | c.2342C>A p.A781D | Missense Mutation (SNP) | VAF 293/788 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as COSV101280966; called by muse, mutect2, varscan2
- CALN1 | c.529G>A p.G177R (on ENST00000329008 / NM_001017440.3; = p.G219R on NM_031468.4) | Missense Mutation (SNP) | VAF 90/950 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV100210008; called by muse, mutect2
- CARMIL1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 36/596 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as rs1012768545, COSV61515927; called by muse, mutect2
- CCDC7 | c.3805G>A p.V1269I | Missense Mutation (SNP) | VAF 151/280 reads (54%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.003); catalogued as rs202101331; called by muse, mutect2, varscan2
- CDK9 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 138/419 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as rs371317161; called by muse, mutect2, varscan2
- CEP89 | c.4C>G p.L2V | Missense Mutation (SNP) | VAF 182/2248 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.121); catalogued as COSV54287600; called by muse, mutect2
- CNTNAP5 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 188/577 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as rs756574947; called by muse, mutect2, varscan2
- COL15A1 | c.3664G>T p.A1222S | Missense Mutation (SNP) | VAF 102/337 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775533962; called by muse, mutect2, varscan2
- CRP | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 247/994 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs769752475, COSV99660768; called by muse, mutect2, varscan2
- CSMD3 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52235767; called by muse, mutect2, varscan2
- CUL7 | c.1837C>G p.P613A | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54819388; called by muse, mutect2, varscan2
- CYP2U1 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 185/552 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as rs763925185; called by muse, mutect2, varscan2
- DNAH17 | c.6035C>T p.S2012L | Missense Mutation (SNP) | VAF 199/312 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs752254470; called by muse, mutect2, varscan2
- EIF3K | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 72/1041 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV50264688; called by muse, mutect2
- EPCAM | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 115/445 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs372660671; called by muse, mutect2, varscan2
- ETF1 | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 97/1456 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as rs1162351595; called by muse, mutect2
- F12 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 36/564 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs778551732; called by muse, mutect2
- FAM171B | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 166/470 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1344370335, COSV59003130; called by muse, mutect2, varscan2
- FLNC | c.7108G>A p.G2370S | Missense Mutation (SNP) | VAF 236/403 reads (59%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as rs201917318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLYWCH1 | c.856G>A p.E286K (on ENST00000253928 / NM_001308068.2; = p.E285K on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/589 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs761336488; called by muse, mutect2, varscan2
- GOLGA4 | c.4462C>A p.L1488I | Missense Mutation (SNP) | VAF 194/317 reads (61%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.876); catalogued as COSV62710358; called by muse, mutect2, varscan2
- GPR6 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 334/740 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as rs955696746, COSV99254581; called by muse, varscan2
- GRM5 | c.788A>G p.K263R | Missense Mutation (SNP) | VAF 107/465 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs753432754; called by muse, mutect2, varscan2
- GSPT2 | c.1277C>G p.S426* | Nonsense Mutation (SNP) | VAF 179/352 reads (51%) | catalogued as COSV61213843; called by muse, mutect2, varscan2
- HMCN1 | c.7477G>T p.E2493* | Nonsense Mutation (SNP) | VAF 87/707 reads (12%) | catalogued as COSV54914603; called by muse, mutect2, varscan2
- IFNLR1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 72/616 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as rs868772417, COSV59526906; called by muse, mutect2, varscan2
- IGKV3-15 | c.157T>G p.L53V | Missense Mutation (SNP) | VAF 290/1070 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs768194531; called by muse, mutect2, varscan2
- IGLV3-12 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 119/337 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs778559176; called by muse, mutect2, varscan2
- IQCG | c.599G>T p.S200I | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs1278317901; called by muse, mutect2, varscan2
- IRX2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 243/450 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs1560949733; called by muse, mutect2, varscan2
- ITGA3 | c.2501C>T p.T834M | Missense Mutation (SNP) | VAF 149/574 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs140248487; called by muse, mutect2, varscan2
- ITSN2 | c.4721A>C p.H1574P | Missense Mutation (SNP) | VAF 117/337 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs751516293; called by muse, mutect2, varscan2
- KHDRBS2 | c.617G>C p.R206P | Missense Mutation (SNP) | VAF 89/296 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV55478958; called by muse, mutect2, varscan2
- KIRREL1 | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 345/1324 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs777659418; called by muse, mutect2, varscan2
- KMT2C | c.6469G>T p.D2157Y | Missense Mutation (SNP) | VAF 149/456 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51293231; called by muse, mutect2, varscan2
- LAMA1 | c.8069T>C p.L2690P | Missense Mutation (SNP) | VAF 368/368 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.434); catalogued as COSV99072068; called by muse, mutect2, varscan2
- LRP1B | c.4519C>T p.Q1507* | Nonsense Mutation (SNP) | VAF 130/539 reads (24%) | catalogued as COSV67259285; called by muse, mutect2, varscan2
- MAST2 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 228/341 reads (67%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as rs781040322; called by muse, mutect2, varscan2
- MC3R | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 135/1592 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54764632; called by muse, mutect2
- MGAM | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 144/450 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs368879552, COSV101516582; called by muse, mutect2, varscan2
- MNDA | c.1001A>C p.K334T | Missense Mutation (SNP) | VAF 364/537 reads (68%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as COSV63739844, COSV63741720; called by muse, mutect2, varscan2
- MRGPRG | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 659/660 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV60040257; called by muse, mutect2, varscan2
- MYH9 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs765414397, COSV53392407; called by muse, mutect2, varscan2
- NALCN | c.4745G>T p.R1582L | Missense Mutation (SNP) | VAF 244/518 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51954405, COSV99215015; called by muse, mutect2, varscan2
- NLGN3 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 224/225 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs768259710, COSV100705169; called by muse, mutect2, varscan2
- NOTCH3 | c.1298A>G p.N433S | Missense Mutation (SNP) | VAF 511/511 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658524; called by muse, mutect2, varscan2
- NRXN3 | c.3262C>T p.P1088S (on ENST00000335750 / NM_001330195.2; = p.P715S on NM_004796.6) | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1189963751; called by muse, mutect2, varscan2
- OGDHL | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 185/536 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs373974919; called by muse, mutect2, varscan2
- OSBPL6 | c.2359G>A p.G787R | Missense Mutation (SNP) | VAF 79/520 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1300715156; called by muse, mutect2, varscan2
- PAQR6 | c.328C>G p.R110G (on ENST00000292291 / NM_001272108.2; = p.R4G on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/2526 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV52745613; called by muse, mutect2
- PCDHGB3 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 374/374 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1430797606, COSV53906319; called by muse, mutect2, varscan2
- PLCB4 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 127/458 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV53804675, COSV53813316; called by muse, mutect2, varscan2
- PLPPR4 | c.71A>G p.E24G | Missense Mutation (SNP) | VAF 55/692 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs577015899; called by muse, mutect2
- POLR2I | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 142/1168 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs752004943; called by muse, mutect2, varscan2
- POSTN | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 72/325 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV65714114; called by muse, mutect2, varscan2
- RAB6B | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs1179735181, COSV99557700; called by muse, mutect2, varscan2
- RGS13 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 37/426 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV67345937; called by muse, mutect2
- RIPOR3 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 54/1007 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747903026; called by muse, mutect2
- RNF135 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 230/735 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs531301373, COSV60434063; called by muse, mutect2, varscan2
- RTN1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 150/416 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as COSV50731541; called by muse, mutect2, varscan2
- SETD1B | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 249/832 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs756584620; called by muse, mutect2, varscan2
- SHROOM2 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 490/491 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368355034, COSV66604270; called by muse, mutect2, varscan2
- SIRT1 | c.269A>C p.Q90P | Missense Mutation (SNP) | VAF 326/829 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as rs1181845230; called by muse, mutect2, varscan2
- SLC7A10 | c.1510_1512del p.E504del | In Frame Del (DEL) | VAF 628/1748 reads (36%) | catalogued as rs773962144; called by pindel, varscan2
- SMARCA4 | c.2438C>G p.S813* | Nonsense Mutation (SNP) | VAF 154/260 reads (59%) | catalogued as COSV60807773; called by muse, mutect2, varscan2
- SNX16 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.672); catalogued as rs1373592072; called by muse, mutect2, varscan2
- SPTBN1 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 125/285 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as rs1392293475; called by muse, mutect2, varscan2
- SPTLC3 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 119/396 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs267605838, COSV65463320; called by muse, mutect2, varscan2
- STOX2 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs770188476; called by muse, mutect2, varscan2
- SYNDIG1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 391/1271 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as rs144760628; called by muse, mutect2, varscan2
- TBX20 | c.143A>C p.K48T | Missense Mutation (SNP) | VAF 252/370 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as COSV101282375, COSV101282400; called by muse, mutect2, varscan2
- TDRD9 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 88/544 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as rs373060575; called by muse, mutect2, varscan2
- TP53 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 517/519 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52708806, COSV52766179, COSV52793434; called by muse, mutect2
- TRPM2 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs369318694; called by muse, mutect2, varscan2
- TRPM2 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 311/866 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs767979728, COSV55971241; called by muse, mutect2, varscan2
- TTC22 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 126/638 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs770467589; called by muse, mutect2, varscan2
- TTC3 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 164/477 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV61287527; called by muse, mutect2, varscan2
- TTN | c.78822A>C p.Q26274H (on ENST00000591111; = p.Q18850H on NM_003319.4) | Missense Mutation (SNP) | VAF 189/309 reads (61%) | PolyPhen benign (0.003); catalogued as COSV59950622; called by muse, mutect2, varscan2
- UBL3 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV101041509; called by muse, mutect2
- URI1 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 104/1465 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1194138839; called by muse, mutect2
- WNT16 | c.850C>A p.L284M (on ENST00000222462 / NM_057168.2; = p.L274M on NM_016087.2) | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV55976832; called by muse, mutect2, varscan2
- XIRP2 | c.8445A>C p.E2815D (on ENST00000628543; = p.E2990D on NM_152381.6) | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs1015438119; called by muse, mutect2, varscan2
- ZBTB7A | c.1447A>T p.R483* | Nonsense Mutation (SNP) | VAF 440/440 reads (100%) | catalogued as COSV99075740; called by muse, mutect2, varscan2
- ZNF785 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 581/582 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201848622, COSV67876261; called by muse, mutect2, varscan2
- ABCB1 | c.3206T>A p.V1069E | Missense Mutation (SNP) | VAF 307/2140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB4 | c.124G>C p.V42L | Missense Mutation (SNP) | VAF 135/1117 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGB | c.1064A>G p.E355G | Missense Mutation (SNP) | VAF 137/299 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL2 | c.1433A>T p.K478M | Missense Mutation (SNP) | VAF 193/271 reads (71%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AGTPBP1 | c.1389G>T p.E463D (on ENST00000357081 / NM_001330701.2; = p.E423D on NM_015239.2) | Missense Mutation (SNP) | VAF 117/405 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- AKAP6 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 264/401 reads (66%) | called by muse, mutect2, varscan2
- ANKRD27 | c.2319G>C p.R773S | Missense Mutation (SNP) | VAF 403/2967 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AP4E1 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 131/203 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ARHGEF16 | c.2019C>G p.D673E | Missense Mutation (SNP) | VAF 110/650 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID1B | c.2540G>T p.S847I | Missense Mutation (SNP) | VAF 390/392 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ASAP2 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 124/490 reads (25%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AURKAIP1 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 26/714 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2
- BMP7 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 389/1516 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- BTBD8 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 205/332 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C1QL2 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 389/833 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C4orf47 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 171/254 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- C7orf25 | c.62C>G p.A21G | Missense Mutation (SNP) | VAF 29/430 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- CACNA1E | c.443del p.F148Sfs*39 | Frame Shift Del (DEL) | VAF 715/1384 reads (52%) | called by mutect2, pindel, varscan2
- CDH19 | c.1352T>A p.I451N | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- CDT1 | c.1587_1607del p.I532_H538del | In Frame Del (DEL) | VAF 138/585 reads (24%) | called by mutect2, pindel, varscan2
- CEP350 | c.2804T>G p.F935C | Missense Mutation (SNP) | VAF 158/1039 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CLSTN2 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CNBD2 | c.1403T>A p.I468K (on ENST00000373973 / NM_001365709.1; = p.I464K on NM_080834.4) | Missense Mutation (SNP) | VAF 249/716 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL3A1 | c.1082C>A p.S361* | Nonsense Mutation (SNP) | VAF 83/288 reads (29%) | called by mutect2, varscan2
- COL4A1 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 178/738 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPS9 | c.2T>A p.M1? (on ENST00000607357 / NM_001163424.2; = p.M22K on NM_138336.1) | Translation Start Site (SNP) | VAF 58/911 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- CREB3L4 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 111/1039 reads (11%) | called by muse, mutect2, varscan2
- CSMD2 | c.6457T>C p.Y2153H | Missense Mutation (SNP) | VAF 356/545 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTTN | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 130/2330 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- DCAF12L1 | c.877A>T p.S293C | Missense Mutation (SNP) | VAF 447/448 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DGKI | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 231/365 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- DIDO1 | c.6508G>T p.D2170Y | Missense Mutation (SNP) | VAF 225/1474 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- EGFL6 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF2AK3 | c.639G>T p.R213S | Missense Mutation (SNP) | VAF 48/455 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EML5 | c.5129T>G p.L1710R (on ENST00000380664; = p.L1718R on NM_183387.3) | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ENO3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 200/200 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- EPHA6 | c.3373_3375del p.E1125del | In Frame Del (DEL) | VAF 69/289 reads (24%) | called by mutect2, pindel, varscan2
- EPHA7 | c.2463C>A p.S821R | Missense Mutation (SNP) | VAF 153/405 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F5 | c.4342C>G p.L1448V | Missense Mutation (SNP) | VAF 215/830 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAM78B | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 707/1078 reads (66%) | SIFT tolerated (1); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- FAT4 | c.8742del p.K2914Nfs*22 | Frame Shift Del (DEL) | VAF 83/280 reads (30%) | called by mutect2, pindel, varscan2
- FOXA2 | c.919dup p.S307Kfs*55 (on ENST00000377115 / NM_153675.3; = p.S313Kfs*55 on NM_021784.5) | Frame Shift Ins (INS) | VAF 184/1337 reads (14%) | called by mutect2, varscan2
- FOXA2 | c.918delinsAA p.S307Kfs*55 (on ENST00000377115 / NM_153675.3; = p.S313Kfs*55 on NM_021784.5) | Frame Shift Ins (INS) | VAF 190/1683 reads (11%) | called by mutect2*, pindel, varscan2*
- FOXM1 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 66/1065 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FRK | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 119/199 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABPB2 | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 724/1038 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GAS2L1 | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 156/702 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by mutect2, varscan2
- GGT1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 148/504 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- GGTLC1 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 149/1574 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2
- GLRB | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 174/283 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GSK3B | c.913T>C p.F305L (on ENST00000264235 / NM_001146156.2; = p.F318L on NM_002093.4) | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- HAO2 | c.14_26del p.C5Ffs*44 | Frame Shift Del (DEL) | VAF 187/345 reads (54%) | called by mutect2, pindel, varscan2
- HEG1 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 24/626 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.361); called by muse, mutect2
- HRC | c.1529A>G p.H510R | Missense Mutation (SNP) | VAF 196/746 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, varscan2
- HUWE1 | c.1593G>T p.V531= | Splice Region (SNP) | VAF 32/289 reads (11%) | called by muse, varscan2
- IFNLR1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 72/620 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV3-11 | c.303A>C p.E101D | Missense Mutation (SNP) | VAF 263/593 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGKV6D-41 | c.297A>C p.E99D | Missense Mutation (SNP) | VAF 128/601 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- IPO13 | c.2017G>A p.G673R | Missense Mutation (SNP) | VAF 102/355 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IVL | c.1028T>G p.L343R | Missense Mutation (SNP) | VAF 338/1320 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- KCNA4 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 74/900 reads (8%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2
- KERA | c.512T>G p.L171R | Missense Mutation (SNP) | VAF 137/441 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF13A | c.3895T>A p.Y1299N | Missense Mutation (SNP) | VAF 129/222 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- KIRREL2 | c.568A>C p.T190P | Missense Mutation (SNP) | VAF 331/1346 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- KNDC1 | c.1934G>A p.G645E | Missense Mutation (SNP) | VAF 94/1152 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- KNTC1 | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- KRTAP5-9 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 124/4734 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- KSR2 | c.1274G>T p.C425F | Missense Mutation (SNP) | VAF 166/542 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- LGI2 | c.1220A>C p.K407T | Missense Mutation (SNP) | VAF 326/461 reads (71%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- LRRC8C | c.2321G>A p.C774Y | Missense Mutation (SNP) | VAF 129/422 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MALRD1 | c.4727G>C p.R1576P | Missense Mutation (SNP) | VAF 193/360 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- MALRD1 | c.5948A>C p.N1983T | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MID1 | c.59del p.P20Lfs*19 | Frame Shift Del (DEL) | VAF 424/590 reads (72%) | called by mutect2, pindel, varscan2
- MIDN | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 500/500 reads (100%) | called by muse, mutect2, varscan2
- MRLN | c.37A>C p.T13P | Missense Mutation (SNP) | VAF 74/205 reads (36%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- MTUS2 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 207/423 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MYO1A | c.333C>A p.S111R | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO5B | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 254/254 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NAA35 | c.1586T>G p.L529R | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NBPF12 | c.922A>G p.S308G | Missense Mutation (SNP) | VAF 95/1449 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.304); called by muse, mutect2
- NCOA3 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 334/958 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- NCOA6 | c.3155A>C p.Q1052P | Missense Mutation (SNP) | VAF 385/1092 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, varscan2
- NFATC1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 443/444 reads (100%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NFKBIZ | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 173/525 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- NPIPB2 | c.802C>T p.Q268* (on ENST00000399147; = p.Q128* on NM_001355514.1) | Nonsense Mutation (SNP) | VAF 119/719 reads (17%) | called by muse, mutect2, varscan2
- NRG1 | c.1700G>T p.S567I (on ENST00000405005 / NM_013964.5; = p.S572I on NM_013956.5) | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NRXN1 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 150/548 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NUP205 | c.4280A>C p.Y1427S | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- OR13C4 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 74/438 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- OR2T33 | c.857del p.L286Pfs*5 | Frame Shift Del (DEL) | VAF 233/486 reads (48%) | called by mutect2, pindel, varscan2
- OR9G1 | c.624C>G p.C208W | Missense Mutation (SNP) | VAF 174/952 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- OSBPL10 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PCLO | c.1790T>G p.L597R | Missense Mutation (SNP) | VAF 248/1736 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PDE6H | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 119/400 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDYN | c.25G>C p.A9P | Missense Mutation (SNP) | VAF 155/533 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- PGPEP1L | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 108/499 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PIWIL2 | c.1398A>T p.E466D | Missense Mutation (SNP) | VAF 83/338 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.1844T>G p.V615G | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCD1 | c.703A>C p.T235P | Missense Mutation (SNP) | VAF 188/627 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- POT1 | c.488A>T p.D163V | Missense Mutation (SNP) | VAF 128/387 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PRR14 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 226/743 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN13 | c.2558T>G p.I853R | Missense Mutation (SNP) | VAF 90/392 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PTRH2 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 105/355 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- RGMB | c.592C>G p.Q198E (on ENST00000513185 / NM_001366508.1; = p.Q239E on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGPD4 | c.4576T>A p.S1526T | Missense Mutation (SNP) | VAF 57/600 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RGS4 | c.240G>C p.L80F | Missense Mutation (SNP) | VAF 62/830 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHBDL1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 248/740 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, varscan2
- RPE | c.419T>G p.V140G (on ENST00000359429 / NM_001318926.1; = p.V90G on NM_006916.2) | Missense Mutation (SNP) | VAF 242/575 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SACS | c.12529dup p.Y4177Lfs*11 | Frame Shift Ins (INS) | VAF 227/574 reads (40%) | called by mutect2, pindel, varscan2
- SCN7A | c.4489_4504del p.E1497Lfs*9 | Frame Shift Del (DEL) | VAF 46/422 reads (11%) | called by mutect2, pindel
- SEC24B | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- SLC25A21 | c.787A>C p.I263L | Missense Mutation (SNP) | VAF 133/375 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC8A1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 123/450 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPPL2A | c.478A>T p.M160L | Missense Mutation (SNP) | VAF 108/335 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STARD9 | c.12697A>G p.S4233G | Missense Mutation (SNP) | VAF 78/440 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- STEAP2 | c.1403G>A p.S468N | Missense Mutation (SNP) | VAF 56/1500 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- STON1 | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 25/469 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- STYX | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 99/192 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TGFBR2 | c.725T>G p.L242R | Missense Mutation (SNP) | VAF 176/525 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOPAZ1 | c.280T>A p.S94T | Missense Mutation (SNP) | VAF 187/583 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRGV1 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 262/393 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRGV5 | c.227T>A p.V76E | Missense Mutation (SNP) | VAF 85/396 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- TRIM23 | c.572T>A p.L191* | Nonsense Mutation (SNP) | VAF 276/276 reads (100%) | called by muse, mutect2, varscan2
- TRPA1 | c.3096A>T p.E1032D | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPC4 | c.1775T>A p.F592Y | Missense Mutation (SNP) | VAF 197/413 reads (48%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UBC | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 391/595 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UNC80 | c.7362A>C p.E2454D | Missense Mutation (SNP) | VAF 95/346 reads (27%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- UPK1A | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 746/992 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- VPS13D | c.11528A>G p.N3843S | Missense Mutation (SNP) | VAF 168/473 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- WDR36 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 109/109 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WFDC9 | c.194A>T p.H65L | Missense Mutation (SNP) | VAF 93/775 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- WWC1 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 16/542 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2
- ZBTB4 | c.1332C>G p.N444K | Missense Mutation (SNP) | VAF 71/635 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF473 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 188/656 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF492 | c.1487A>C p.K496T | Missense Mutation (SNP) | VAF 178/189 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ZNF587B | c.600A>T p.K200N | Missense Mutation (SNP) | VAF 304/1360 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ZNF606 | c.1379A>C p.K460T | Missense Mutation (SNP) | VAF 828/1278 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF710 | c.1079T>G p.F360C | Missense Mutation (SNP) | VAF 175/619 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF737 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 148/226 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ZNRF1 | c.183dup p.S62Qfs*51 | Frame Shift Ins (INS) | VAF 500/1221 reads (41%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.396C>T p.R132= | Silent (SNP) | VAF 186/402 reads (46%) | called by muse, mutect2, varscan2
- ADSL | c.1398T>C p.Y466= | Silent (SNP) | VAF 149/246 reads (61%) | called by muse, mutect2, varscan2
- AEBP2 | c.1503G>A p.L501= | Silent (SNP) | VAF 51/280 reads (18%) | called by muse, mutect2, varscan2
- AFF2 | c.1743T>G p.A581= | Silent (SNP) | VAF 433/433 reads (100%) | called by muse, mutect2, varscan2
- AGAP4 | c.1242C>T p.A414= | Silent (SNP) | VAF 34/1052 reads (3%) | called by muse, mutect2
- AKNA | c.3225G>A p.Q1075= | Silent (SNP) | VAF 118/381 reads (31%) | called by muse, mutect2, varscan2
- ANKS4B | c.93C>T p.D31= | Silent (SNP) | VAF 349/349 reads (100%) | catalogued as rs761541321; called by muse, mutect2, varscan2
- C13orf42 | c.174C>T p.S58= | Silent (SNP) | VAF 73/606 reads (12%) | called by muse, mutect2, varscan2
- CAPN8 | c.279G>T p.T93= | Silent (SNP) | VAF 74/535 reads (14%) | called by muse, mutect2, varscan2
- CCDC171 | c.3627C>G p.V1209= | Silent (SNP) | VAF 185/185 reads (100%) | called by muse, mutect2, varscan2
- CCDC185 | c.1860C>T p.N620= | Silent (SNP) | VAF 98/302 reads (32%) | called by muse, mutect2, varscan2
- CCRL2 | c.426G>A p.R142= | Silent (SNP) | VAF 165/466 reads (35%) | called by muse, mutect2, varscan2
- CES5A | c.1512C>T p.N504= (on ENST00000290567 / NM_001143685.2; = p.N454= on NM_145024.3) | Silent (SNP) | VAF 212/330 reads (64%) | catalogued as rs186119494, COSV51865025; called by muse, mutect2, varscan2
- CFAP52 | c.1545C>T p.F515= | Silent (SNP) | VAF 267/267 reads (100%) | called by muse, mutect2, varscan2
- CFHR4 | c.276A>G p.V92= (on ENST00000367416 / NM_001201551.2; = p.V93= on NM_001201550.3) | Silent (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- CLEC18A | c.1323G>A p.R441= | Silent (SNP) | VAF 45/964 reads (5%) | called by muse, mutect2
- CLEC18B | c.1350G>A p.R450= | Silent (SNP) | VAF 45/427 reads (11%) | called by muse, mutect2
- COL12A1 | c.1182C>G p.L394= | Silent (SNP) | VAF 214/472 reads (45%) | called by muse, mutect2, varscan2
- COPS5 | c.552C>T p.G184= | Silent (SNP) | VAF 66/276 reads (24%) | catalogued as rs570152372, COSV100769935; called by muse, mutect2, varscan2
- CROT | c.1254G>A p.T418= | Silent (SNP) | VAF 228/1613 reads (14%) | catalogued as rs142498632; called by muse, mutect2, varscan2
- CSAD | c.1461G>A p.E487= (on ENST00000444623 / NM_001244705.2; = p.E514= on NM_015989.5) | Silent (SNP) | VAF 117/460 reads (25%) | called by muse, mutect2, varscan2
- DDX24 | c.1746C>T p.F582= | Silent (SNP) | VAF 30/844 reads (4%) | catalogued as rs373851699; called by muse, mutect2
- DICER1 | c.5196G>A p.L1732= | Silent (SNP) | VAF 135/442 reads (31%) | called by muse, mutect2, varscan2
- DIMT1 | c.579G>A p.K193= | Silent (SNP) | VAF 95/187 reads (51%) | called by muse, mutect2, varscan2
- DNAH11 | c.3114T>G p.T1038= | Silent (SNP) | VAF 69/371 reads (19%) | catalogued as COSV60937946; called by muse, mutect2, varscan2
- EIF3I | c.18G>T p.L6= | Silent (SNP) | VAF 147/433 reads (34%) | catalogued as rs1379660245; called by muse, mutect2, varscan2
- F8 | c.2766C>T p.S922= | Silent (SNP) | VAF 172/363 reads (47%) | catalogued as CD082109, COSV64278626; called by muse, mutect2, varscan2
- FOXD4 | c.378G>A p.T126= | Silent (SNP) | VAF 74/941 reads (8%) | called by muse, mutect2
- FOXD4L1 | c.387G>A p.T129= | Silent (SNP) | VAF 328/1111 reads (30%) | catalogued as rs1431191267; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1176G>A p.K392= | Silent (SNP) | VAF 62/878 reads (7%) | called by muse, mutect2
- GPR137C | c.759C>A p.V253= | Silent (SNP) | VAF 269/401 reads (67%) | called by muse, mutect2, varscan2
- HEXB | c.1572C>T p.D524= | Silent (SNP) | VAF 107/252 reads (42%) | catalogued as rs770560389, COSV54666967; ClinVar: likely benign; called by muse, mutect2, varscan2
- HOXB4 | c.603C>T p.L201= | Silent (SNP) | VAF 104/635 reads (16%) | called by muse, mutect2, varscan2
- IFNLR1 | c.444C>G p.P148= | Silent (SNP) | VAF 224/1039 reads (22%) | called by muse, mutect2, varscan2
- INTS1 | c.1998G>A p.P666= | Silent (SNP) | VAF 156/736 reads (21%) | catalogued as rs1251565692; called by muse, mutect2
- JPH2 | c.1380G>A p.A460= | Silent (SNP) | VAF 460/1495 reads (31%) | catalogued as rs531877510; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- KRTAP2-4 | c.339C>T p.C113= | Silent (SNP) | VAF 350/634 reads (55%) | catalogued as rs751495363, COSV67458593; called by muse, mutect2, varscan2
- LRRC28 | c.841C>T p.L281= | Silent (SNP) | VAF 95/382 reads (25%) | called by muse, mutect2, varscan2
- MAP7 | c.1476G>A p.E492= | Silent (SNP) | VAF 260/485 reads (54%) | called by muse, mutect2, varscan2
- MRAP2 | c.360C>A p.I120= | Silent (SNP) | VAF 18/592 reads (3%) | catalogued as COSV57635477; called by muse, mutect2
- MTARC1 | c.750A>C p.A250= | Silent (SNP) | VAF 55/273 reads (20%) | called by muse, mutect2, varscan2
- MUC17 | c.3057A>G p.E1019= | Silent (SNP) | VAF 294/1641 reads (18%) | catalogued as rs1455388524, COSV60294420; called by muse, mutect2
- MYBPC2 | c.3192G>A p.S1064= | Silent (SNP) | VAF 95/523 reads (18%) | catalogued as rs750959477; called by muse, mutect2, varscan2
- MYL4 | c.225C>T p.Y75= | Silent (SNP) | VAF 97/461 reads (21%) | catalogued as rs372355856; called by muse, mutect2, varscan2
- MYT1 | c.3333C>T p.S1111= | Silent (SNP) | VAF 251/1203 reads (21%) | catalogued as COSV60509087; called by muse, mutect2, varscan2
- NPAS3 | c.909C>T p.T303= (on ENST00000356141 / NM_001164749.2; = p.T271= on NM_022123.3) | Silent (SNP) | VAF 207/338 reads (61%) | catalogued as rs746089574; called by muse, mutect2, varscan2
- NRP2 | c.1728G>A p.E576= | Silent (SNP) | VAF 165/1239 reads (13%) | catalogued as COSV55931861; called by muse, mutect2, varscan2
- ONECUT3 | c.21C>T p.S7= | Silent (SNP) | VAF 325/325 reads (100%) | called by muse, mutect2, varscan2
- PAK3 | c.1323A>G p.P441= (on ENST00000262836 / NM_001324328.2; = p.P426= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 221/435 reads (51%) | catalogued as rs150235270; called by muse, mutect2, varscan2
- PEX2 | c.633C>T p.I211= | Silent (SNP) | VAF 325/460 reads (71%) | catalogued as COSV63813033; called by muse, mutect2, varscan2
- PLA2G15 | c.894C>T p.F298= | Silent (SNP) | VAF 127/595 reads (21%) | catalogued as COSV54722428; called by muse, mutect2, varscan2
- PNP | c.327C>T p.D109= | Silent (SNP) | VAF 126/375 reads (34%) | called by muse, mutect2, varscan2
- POR | c.1227C>T p.A409= | Silent (SNP) | VAF 143/2463 reads (6%) | catalogued as rs782563724; called by muse, mutect2
- POU4F1 | c.537C>T p.G179= | Silent (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- PPP2R3A | c.3171T>C p.N1057= | Silent (SNP) | VAF 151/459 reads (33%) | called by muse, mutect2, varscan2
- PTCD3 | c.1071A>G p.L357= | Silent (SNP) | VAF 280/404 reads (69%) | called by muse, mutect2, varscan2
- RALBP1 | c.1257G>T p.G419= | Silent (SNP) | VAF 64/270 reads (24%) | called by mutect2, varscan2
- SHANK1 | c.4089G>A p.A1363= | Silent (SNP) | VAF 156/745 reads (21%) | called by muse, mutect2, varscan2
- SHD | c.189C>A p.S63= | Silent (SNP) | VAF 66/665 reads (10%) | called by muse, mutect2, varscan2
- SLC4A10 | c.924A>T p.G308= | Silent (SNP) | VAF 87/383 reads (23%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.1527C>T p.I509= | Silent (SNP) | VAF 141/457 reads (31%) | catalogued as COSV99480286; called by muse, mutect2, varscan2
- SPATA31A7 | c.1221T>C p.S407= | Silent (SNP) | VAF 171/320 reads (53%) | called by muse, mutect2, varscan2
- SYNE1 | c.13479C>G p.V4493= (on ENST00000367255 / NM_182961.4; = p.V4422= on NM_033071.3) | Silent (SNP) | VAF 49/449 reads (11%) | called by muse, mutect2, varscan2
- SYNPO2 | c.531C>T p.R177= | Silent (SNP) | VAF 231/388 reads (60%) | catalogued as rs139521362; called by muse, mutect2, varscan2
- TAS2R19 | c.816T>G p.P272= | Silent (SNP) | VAF 173/881 reads (20%) | called by muse, mutect2, varscan2
- TLE1 | c.963G>T p.T321= | Silent (SNP) | VAF 166/598 reads (28%) | called by muse, mutect2, varscan2
- TRBJ2-4 | c.36C>G p.T12= | Silent (SNP) | VAF 232/704 reads (33%) | called by muse, mutect2, varscan2
- TRPM3 | c.4914C>T p.R1638= (on ENST00000357533 / NM_001366142.2; = p.R1493= on NM_020952.6) | Silent (SNP) | VAF 88/476 reads (18%) | catalogued as rs765557409, COSV100676398; called by muse, mutect2, varscan2
- TTN | c.95679A>G p.K31893= (on ENST00000591111; = p.K24469= on NM_003319.4) | Silent (SNP) | VAF 228/388 reads (59%) | called by muse, mutect2, varscan2
- TTN | c.8205C>T p.V2735= (on ENST00000591111; = p.V2689= on NM_003319.4) | Silent (SNP) | VAF 136/398 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.6594T>C p.T2198= (on ENST00000591111; = p.T2152= on NM_003319.4) | Silent (SNP) | VAF 274/422 reads (65%) | catalogued as COSV100592265; called by muse, mutect2, varscan2
- USP42 | c.3681C>T p.D1227= | Silent (SNP) | VAF 46/412 reads (11%) | catalogued as rs887759670; called by muse, mutect2, varscan2
- WNK2 | c.2394T>C p.I798= | Silent (SNP) | VAF 176/539 reads (33%) | catalogued as rs1430134543; called by muse, mutect2, varscan2
- ZNF354C | c.642A>G p.K214= | Silent (SNP) | VAF 288/289 reads (100%) | called by muse, mutect2, varscan2
- ZNF471 | c.1062T>G p.A354= | Silent (SNP) | VAF 335/336 reads (100%) | called by muse, mutect2, varscan2
- ZNF556 | c.972C>T p.F324= | Silent (SNP) | VAF 38/386 reads (10%) | catalogued as rs745591315, COSV100298610; called by muse, mutect2
- ZNF804B | c.204G>A p.Q68= | Silent (SNP) | VAF 96/1584 reads (6%) | catalogued as COSV60825097; called by muse, mutect2
- ZNF814 | c.1731G>T p.G577= | Silent (SNP) | VAF 1485/1491 reads (100%) | called by muse, mutect2, varscan2
- ABHD5 | c.774-734G>A | Intron (SNP) | VAF 235/355 reads (66%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+2073C>T | Intron (SNP) | VAF 121/338 reads (36%) | called by muse, mutect2, varscan2
- CAPZB | c.3+1161A>C | Intron (SNP) | VAF 56/287 reads (20%) | called by muse, mutect2, varscan2
- DNAJA4 | c.132+707C>T | Intron (SNP) | VAF 307/434 reads (71%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46862C>T | Intron (SNP) | VAF 60/1714 reads (4%) | called by muse, mutect2
- RNU6-784P | chr4:70705023 G>C | 5'Flank (SNP) | VAF 248/973 reads (25%) | called by muse, mutect2, varscan2
- TUBB6 | c.278-88T>A | Intron (SNP) | VAF 27/515 reads (5%) | called by muse, mutect2
- WDR64 | c.*197C>T | 3'UTR (SNP) | VAF 78/422 reads (18%) | called by muse, mutect2, varscan2
